MMRF case MMRF_2000 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0827cff2-e65b-4dfe-afe5-5f902390d4af

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 49.4 years (18,060 days); ISS stage: I; Days to last known disease status: 991 days (2.7 years); Days to last follow up: 991 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 18 days; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 126 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 287 days; Days to treatment end: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 287 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 638 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.495 mg/dL; Immunoglobulin G 67.6 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 3.76 ×10⁹/L; Platelets 353 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 10.3 g/dL; Glucose 6.27 mmol/L; C-Reactive Protein 3.33 mg/dL.
- Day 105 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.543 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.706 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.74 g/L; Beta 2 Microglobulin 1.13 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 306 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 8.75 mmol/L.
- Day 175 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.999 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.824 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.27 mmol/L.
- Day 287 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.624 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 9.54 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.07 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 313 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 371 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.692 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 7.27 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 6.74 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 462 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.676 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 560 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.822 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.495 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 638 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 7.79 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 7.48 mmol/L.
- Day 749 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 6.33 mmol/L.
- Day 854 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.879 mg/dL; Immunoglobulin G 7.67 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 5.72 mmol/L.
- Day 939: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.625 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 14.7 ×10⁹/L; Absolute Neutrophil 11.9 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 11 mmol/L.
- Day 991: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 7.89 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.15 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 1: Weight: 78 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2000_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2000_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
